Somatic mutation profile of tumor specimen TCGA-A5-A1OF-01A (aliquot TCGA-A5-A1OF-01A-11D-A14G-09) from TCGA case TCGA-A5-A1OF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: High Grade; Age at diagnosis: 47.4 years (17,308 days).
Specimen TCGA-A5-A1OF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb6d6f74-a1df-4607-af93-80845a33ca6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A1OF-10A (Blood Derived Normal), aliquot TCGA-A5-A1OF-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05b65962-0707-45e3-a47a-94df5fbba96f

The open-access MAF lists 12,694 somatic variants for this specimen: 9,303 protein-altering or splice-affecting, 3,135 silent, 256 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,363, Silent 3,135, Nonsense Mutation 556, Splice Site 211, Intron 101, Splice Region 93, RNA 60, Frame Shift Ins 41, 3'UTR 32, Frame Shift Del 26, 5'Flank 25, 3'Flank 25.

Variants (750 of 12,694; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAGAB | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as rs746488412, CM128797, COSV56018590; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781617345, CM073984, COSV56848476; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAT1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370720208, CM075969; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.6472C>T p.R2158* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | hotspot (GDC flag); catalogued as COSV61370611, COSV61381711; called by muse, varscan2
- COL7A1 | c.5096C>T p.P1699L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs121912845, CM023055; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCX | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs587783568, CM023363, CM087666; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DNMT3B | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121908943, CM993140, COSV52416513; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DPYD | c.1524+1G>A p.X508_splice | Splice Site (SNP) | VAF 13/37 reads (35%) | catalogued as rs1057517126; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FANCA | c.3624C>T p.S1208= | Splice Region (SNP) | VAF 20/67 reads (30%) | catalogued as rs149797103, CS080700; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FANCA | c.3163C>T p.R1055W | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753063086, CM990585, COSV59799105; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FARSB | c.848+1G>A p.X283_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as rs777071414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.6453C>T p.C2151= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs794728251, CM940769, CS118012, COSV57318600; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FUS | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs121909671, CM091091, CM104703, COSV99568433; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GAA | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121907937, CM082740, CM910166, COSV56408643; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GRIN1 | c.2443G>A p.G815R | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs797044925, CM155880, CM162177; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HERC2 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs397518474, CM1211539, COSV99871359; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HEXA | c.1305C>T p.Y435= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs587779406, CS102998, COSV51507879; ClinVar: likely pathogenic; called by muse, varscan2
- HOGA1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs796052086, CM118808; ClinVar: pathogenic; called by muse, mutect2, varscan2
- INSR | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886037750, CM160363, COSV100252971; ClinVar: pathogenic; called by muse, varscan2
- KCNH2 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs794728383, CM1211301, COSV51221089; ClinVar: likely pathogenic; called by muse, mutect2
- KCNQ1 | c.1766G>A p.G589D | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs120074190, CM983670; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057516085, CM136080, COSV100610433; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LMNA | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs58932704, CM990813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MASP1 | c.1303+5186C>T | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs377074720, COSV56227624; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MCPH1 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906961, CM107962, COSV100766054; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MECP2 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs61751450, CM001234, COSV57654028; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MSH6 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as rs63750617, CM045069, COSV52282972, COSV52287949; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs397516135, HM0650, COSV62519421; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NEPRO | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236015814; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CB | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 30/76 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56683107, COSV56689255; called by muse, varscan2
- PIK3R1 | c.1519G>T p.E507* (on ENST00000521381 / NM_181523.3; = p.E237* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as rs1554051161, COSV57142279; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PKD1 | c.7927C>T p.R2643C | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452322332, CD123955, CM074416; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PNLIP | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746000327, CM141074, COSV65039918, COSV65040496; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPT1 | c.487C>T p.R163* (on ENST00000433473; = p.R164* on NM_000310.4) | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs386833649, CM981630, COSV65655910; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 54/93 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.6127+1G>A p.X2043_splice | Splice Site (SNP) | VAF 4/27 reads (15%) | catalogued as rs1283302989, COSV99052015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SCN1A | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918770, CD032498, CM031732, CM159412, COSV57670403, COSV57693028; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC4A1 | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866727908, CM973089, COSV52260138, COSV52262764; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SOX10 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as rs1555939523, CP025182, CX103666; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as CM087281, CM159290, COSV52670715, COSV52718021, COSV53252418; called by muse, mutect2, varscan2
- TTN | c.59530C>T p.R19844* (on ENST00000591111; = p.R12420* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as rs768345594, CM1514681, COSV60142285; ClinVar: likely pathogenic; called by muse, varscan2
- TUBB2A | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.964); catalogued as rs1554122907; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- VWF | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs772203447, CM083206, COSV54614676; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs747822956, COSV54050523; called by muse, mutect2
- A1CF | c.1535C>T p.T512M (on ENST00000373993 / NM_138932.2; = p.T504M on NM_014576.4) | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1167572371; called by muse, varscan2
- A4GALT | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1037960020, COSV50745045; called by muse, mutect2, varscan2
- A4GNT | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV52628454; called by muse, mutect2, varscan2
- A4GNT | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757476825; called by muse, mutect2, varscan2
- AADACL3 | c.473A>G p.K158R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV60199825; called by muse, mutect2, varscan2
- AARS1 | c.2089G>A p.V697I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.386); catalogued as rs368191672; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AASDH | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs59713248; called by muse, mutect2, varscan2
- AATF | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770259796; called by muse, mutect2, varscan2
- ABCA1 | c.655A>G p.R219G | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs778562903; called by muse, mutect2, varscan2
- ABCA10 | c.3673G>A p.V1225I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as rs751195093; called by muse, mutect2, varscan2
- ABCA12 | c.4642G>A p.A1548T (on ENST00000272895 / NM_173076.3; = p.A1230T on NM_015657.3) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754893598, COSV55974837; called by muse, mutect2, varscan2
- ABCA12 | c.1061+1G>T p.X354_splice (on ENST00000272895 / NM_173076.3; = p.X36_splice on NM_015657.3) | Splice Site (SNP) | VAF 9/44 reads (20%) | catalogued as COSV55956443; called by muse, mutect2, varscan2
- ABCA13 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757660175; called by muse, mutect2, varscan2
- ABCA13 | c.10253G>A p.R3418H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs764681827, COSV71287219, COSV71287487; called by muse, mutect2, varscan2
- ABCA13 | c.14534A>C p.H4845P | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777707865; called by mutect2, varscan2
- ABCA2 | c.1583C>T p.A528V (on ENST00000614293; = p.A498V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs368150231; called by muse, mutect2, varscan2
- ABCA3 | c.1822C>A p.L608M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV57052395; called by muse, varscan2
- ABCA3 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs780116425, COSV57059379; called by muse, mutect2, varscan2
- ABCA4 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV64671575; called by muse, varscan2
- ABCA7 | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949890542; called by muse, mutect2, varscan2
- ABCA7 | c.5882G>A p.R1961Q | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs776765059; called by muse, mutect2, varscan2
- ABCA9 | c.433A>G p.R145G | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV60632335; called by muse, mutect2
- ABCB10 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1348176646; called by muse, mutect2, varscan2
- ABCB10 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs751369540; called by muse, mutect2, varscan2
- ABCB5 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1458981091, COSV51706335, COSV51707862; called by muse, mutect2, varscan2
- ABCB6 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs145498806; called by muse, mutect2, varscan2
- ABCC1 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs906081060, COSV60692608; called by muse, mutect2, varscan2
- ABCC10 | c.798C>A p.H266Q (on ENST00000372530 / NM_001198934.2; = p.H223Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55088335; called by muse, mutect2, varscan2
- ABCC10 | c.2351G>A p.R784H (on ENST00000372530 / NM_001198934.2; = p.R756H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs41271275; called by muse, mutect2, varscan2
- ABCC11 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374130441; called by muse, mutect2, varscan2
- ABCC11 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV62326746; called by muse, mutect2, varscan2
- ABCC12 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs1287133996; called by muse, mutect2, varscan2
- ABCC12 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs773323570; called by muse, mutect2, varscan2
- ABCC2 | c.15C>A p.F5L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as COSV64971113; called by muse, mutect2, varscan2
- ABCC6 | c.1125G>T p.K375N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV99229055; called by muse, mutect2, varscan2
- ABCC8 | c.4166T>G p.L1389R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as CM073988, CM112694; called by muse, mutect2, varscan2
- ABCC9 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs1411357079, COSV53985920, COSV99688052; called by muse, mutect2, varscan2
- ABCD1 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM022605; called by muse, varscan2
- ABCF1 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs1561786344, COSV58228142; called by muse, mutect2
- ABCG8 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.105); catalogued as rs1362946455; called by muse, mutect2, varscan2
- ABHD13 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs749263953, COSV101024240, COSV65534301; called by muse, mutect2, varscan2
- ABHD17A | c.410G>A p.R137H (on ENST00000292577 / NM_001130111.2; = p.R188H on NM_031213.4) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.619); catalogued as rs765695569, COSV51751523; called by muse, varscan2
- ABHD3 | c.662T>C p.M221T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1386187047; called by muse, mutect2, varscan2
- ABI3 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1423154843, COSV56800840; called by muse, mutect2, varscan2
- ABI3BP | c.3047G>A p.R1016H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs754106573; called by muse, mutect2, varscan2
- ABL2 | c.413G>A p.G138D (on ENST00000502732 / NM_007314.4; = p.G123D on NM_005158.5) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.602); catalogued as rs760263640; called by muse, mutect2, varscan2
- ABLIM1 | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1373772536; called by muse, mutect2, varscan2
- ABLIM2 | c.1331G>T p.R444M (on ENST00000341937 / NM_001130084.2; = p.R392M on NM_032432.5) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV56402193; called by muse, varscan2
- ABO | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs782445625, COSV101505953; called by muse, mutect2
- ABTB1 | c.958G>A p.V320I (on ENST00000232744 / NM_172027.3; = p.V178I on NM_032548.3) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368990352; called by muse, mutect2, varscan2
- AC008397.2 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1456454360, COSV53208421; called by muse, mutect2
- AC092143.1 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59248011; called by muse, mutect2, varscan2
- ACACB | c.6995G>A p.R2332H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778545831, COSV58129922; called by muse, mutect2, varscan2
- ACE | c.914A>G p.N305S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141186617; called by muse, mutect2, varscan2
- ACKR2 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1350292551, COSV56177017; called by muse, mutect2, varscan2
- ACLY | c.3166G>T p.A1056S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as COSV59863227; called by mutect2, varscan2
- ACMSD | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV51609619; called by muse, varscan2
- ACSF3 | c.1606T>C p.W536R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV58079711; called by muse, mutect2, varscan2
- ACTL7A | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs770746389, COSV100453047; called by muse, mutect2, varscan2
- ACTR10 | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs757930478; called by muse, mutect2, varscan2
- ACTR1A | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs368237331; called by muse, mutect2, varscan2
- ACVRL1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as rs746430008; called by muse, mutect2, varscan2
- ACY3 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV54828873; called by muse, mutect2, varscan2
- ADAM19 | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs759459737; called by muse, mutect2, varscan2
- ADAM2 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs766240507; called by muse, mutect2, varscan2
- ADAM23 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536972155; called by muse, mutect2, varscan2
- ADAM29 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs149968346, COSV63668854; called by muse, mutect2, varscan2
- ADAM29 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as rs748743733, COSV63659968; called by muse, mutect2, varscan2
- ADAM32 | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.216); catalogued as rs375936377; called by muse, varscan2
- ADAM33 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs779317899, COSV62933451; called by muse, mutect2, varscan2
- ADAM7 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51534609; called by muse, mutect2, varscan2
- ADAM8 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as rs1348434636; called by muse, mutect2, varscan2
- ADAMTS10 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555741970, COSV54360829; called by muse, mutect2, varscan2
- ADAMTS12 | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs757718642; called by muse, mutect2, varscan2
- ADAMTS12 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as rs770539917; called by muse, mutect2, varscan2
- ADAMTS13 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs782719456, COSV63020802; called by muse, mutect2, varscan2
- ADAMTS14 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as rs372668477; called by muse, varscan2
- ADAMTS16 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552210881, COSV57007046; called by muse, mutect2, varscan2
- ADAMTS17 | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756837804, COSV51490892; called by muse, mutect2, varscan2
- ADAMTS17 | c.2339A>G p.Y780C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51473426, COSV51478761; called by muse, mutect2, varscan2
- ADAMTS18 | c.3280C>T p.R1094* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as rs775431905, COSV51417329; called by mutect2, varscan2
- ADAMTS18 | c.2704C>T p.R902* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99273515; called by mutect2, varscan2
- ADAMTS2 | c.3319G>T p.E1107* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV52395705; called by mutect2, varscan2
- ADAMTS2 | c.3028G>A p.G1010S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs368690576; called by muse, mutect2, varscan2
- ADAMTS20 | c.1969T>C p.Y657H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1371210742, COSV101239625; called by muse, mutect2, varscan2
- ADAMTS8 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs778449559; called by mutect2, varscan2
- ADAMTSL3 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV54455728; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3668C>T p.A1223V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1380125723; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs765870062, COSV55005303; called by mutect2, varscan2
- ADCK1 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs200983054; called by muse, mutect2, varscan2
- ADCY10 | c.2956G>A p.A986T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs771678044; called by muse, varscan2
- ADCY2 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243719617, COSV57886381; called by muse, mutect2, varscan2
- ADCY2 | c.2311G>A p.V771M | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV57859884; called by muse, mutect2, varscan2
- ADCY3 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV53165018, COSV53166789; called by muse, mutect2, varscan2
- ADCY4 | c.2153T>C p.V718A | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1449406522; called by muse, mutect2, varscan2
- ADCY4 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750690966, COSV60251716; called by muse, mutect2, varscan2
- ADCY7 | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs967639581, COSV54268562; called by muse, mutect2, varscan2
- ADCY7 | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139215312; called by muse, mutect2, varscan2
- ADCYAP1 | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.175); catalogued as COSV52485961; called by muse, varscan2
- ADCYAP1R1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs749208553, COSV58445654; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as COSV58445278; called by muse, mutect2, varscan2
- ADD1 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs913024832, COSV53265909; called by muse, mutect2, varscan2
- ADD3 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV53323400; called by muse, mutect2, varscan2
- ADGRA2 | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs758837731; called by muse, mutect2, varscan2
- ADGRA2 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs372478146, COSV55102467; called by muse, mutect2, varscan2
- ADGRB1 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1164083455; called by muse, mutect2, varscan2
- ADGRB3 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.056); catalogued as rs112866971, COSV65404904; called by muse, mutect2, varscan2
- ADGRD1 | c.2115G>A p.W705* | Nonsense Mutation (SNP) | VAF 13/113 reads (12%) | catalogued as COSV55449834, COSV55453098; called by muse, mutect2, varscan2
- ADGRE1 | c.2326C>A p.L776M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51681661; called by muse, mutect2, varscan2
- ADGRF3 | c.1978C>T p.R660* (on ENST00000311519 / NM_001145168.1; = p.R461* on NM_153835.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as rs116734873; called by muse, mutect2, varscan2
- ADGRF3 | c.1400C>T p.A467V (on ENST00000311519 / NM_001145168.1; = p.A268V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs1188403415; called by muse, varscan2
- ADGRG4 | c.1034C>A p.S345Y | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.054); catalogued as COSV54953822; called by mutect2, varscan2
- ADGRG4 | c.3749G>A p.S1250N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1237016920; called by muse, varscan2
- ADGRG4 | c.3793C>A p.L1265M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99795286; called by muse, varscan2
- ADGRG4 | c.6149C>T p.A2050V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs747025821, COSV54951054; called by muse, mutect2, varscan2
- ADGRG4 | c.8623C>A p.L2875M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99795775; called by muse, varscan2
- ADGRG6 | c.2438G>A p.S813N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV51587613; called by muse, mutect2, varscan2
- ADGRL3 | c.2161G>A p.A721T (on ENST00000506720 / NM_001322402.2; = p.A653T on NM_015236.6) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as COSV72230332; called by muse, mutect2, varscan2
- ADGRL4 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV66059524; called by muse, mutect2, varscan2
- ADGRV1 | c.7844G>A p.G2615D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203664026, COSV67990944; called by muse, mutect2, varscan2
- ADRA2A | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.053); catalogued as COSV54527824; called by muse, mutect2, varscan2
- ADRB2 | c.118A>G p.M40V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs772355060; called by muse, mutect2, varscan2
- ADRM1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1329189722, COSV99441616; called by muse, varscan2
- AFAP1L1 | c.668T>C p.I223T | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs892032328; called by muse, mutect2, varscan2
- AFDN | c.4808C>T p.A1603V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.096); catalogued as rs759940319, COSV60047991; called by muse, mutect2, varscan2
- AFF3 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs1434062146, COSV57867285, COSV57868032; called by muse, mutect2, varscan2
- AFF4 | c.3010C>T p.R1004* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV54800506; called by muse, mutect2, varscan2
- AFG3L2 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52314343; called by muse, mutect2, varscan2
- AGA | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121964907, CM910008, COSV52806361; ClinVar: uncertain significance; called by muse, varscan2
- AGAP1 | c.1855C>T p.R619C (on ENST00000304032 / NM_001037131.3; = p.R566C on NM_014914.5) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs770626614, COSV58328562; called by muse, mutect2, varscan2
- AGAP1 | c.2099C>T p.S700L (on ENST00000304032 / NM_001037131.3; = p.S647L on NM_014914.5) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as rs778729453; called by muse, mutect2, varscan2
- AGBL5 | c.1678C>T p.R560* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV59936819; called by muse, mutect2, varscan2
- AGPAT5 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750274607; called by muse, varscan2
- AHCTF1 | c.6068C>A p.S2023Y (on ENST00000366508; = p.S1997Y on NM_015446.5) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100403625; called by muse, mutect2, varscan2
- AHDC1 | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs746453956, COSV55942312; called by muse, mutect2, varscan2
- AHNAK | c.1647G>T p.E549D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.279); catalogued as COSV57222823; called by muse, mutect2, varscan2
- AHNAK2 | c.15563G>T p.S5188I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV60909088; called by muse, mutect2, varscan2
- AHR | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1246045330, COSV54126188; called by muse, mutect2, varscan2
- AHRR | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs199742068; called by muse, mutect2, varscan2
- AHRR | c.980G>T p.S327I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs1553989610; called by muse, mutect2
- AIFM3 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV59002812; called by muse, mutect2, varscan2
- AIFM3 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as rs1011340614; called by muse, mutect2, varscan2
- AK3 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63347032; called by muse, mutect2, varscan2
- AK5 | c.280C>T p.R94W (on ENST00000354567 / NM_174858.3; = p.R68W on NM_012093.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs747264984, COSV58357394; called by muse, mutect2, varscan2
- AK9 | c.5626G>A p.G1876S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as COSV69850640; called by muse, mutect2, varscan2
- AKAP1 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1039326441; called by muse, mutect2, varscan2
- AKAP12 | c.3502G>T p.D1168Y | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53582597; called by muse, mutect2, varscan2
- AKAP12 | c.4365G>T p.E1455D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as rs943349852, COSV53573607; called by muse, mutect2, varscan2
- AKAP8 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200109371; called by muse, mutect2, varscan2
- AKAP9 | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as rs754329751; called by mutect2, varscan2
- AKAP9 | c.6333G>T p.E2111D (on ENST00000359028; = p.E2079D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100663464; called by muse, mutect2, varscan2
- AKAP9 | c.9367G>A p.A3123T (on ENST00000359028; = p.A3099T on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.135); catalogued as rs1360182925; called by muse, mutect2, varscan2
- AKNA | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56312423; called by muse, mutect2, varscan2
- AKR7L | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs761293299, COSV70167436, COSV70167801; called by muse, mutect2, varscan2
- AL136295.1 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1161486962, COSV55778672; called by muse, mutect2, varscan2
- AL136295.1 | c.1095G>T p.K365N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV55780584; called by muse, mutect2, varscan2
- AL162417.1 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as COSV64404439; called by muse, mutect2, varscan2
- ALDH18A1 | c.1230C>A p.D410E | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64663268; called by muse, mutect2, varscan2
- ALDH1A3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs770345049, COSV60903281; called by muse, mutect2, varscan2
- ALDH1L1 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs140551047; called by muse, mutect2, varscan2
- ALDH2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs201835306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH4A1 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs763369468; called by muse, mutect2, varscan2
- ALDOA | c.485A>G p.K162R (on ENST00000642816 / NM_001243177.4; = p.K108R on NM_184041.5) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405041987; called by muse, mutect2, varscan2
- ALDOA | c.598G>A p.A200T (on ENST00000642816 / NM_001243177.4; = p.A146T on NM_184041.5) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as rs1439374477, COSV57633197; called by muse, mutect2, varscan2
- ALG1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs777348829; called by muse, mutect2, varscan2
- ALG10 | c.1358dup p.I454Hfs*12 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs763725201; called by pindel, varscan2
- ALG12 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV58207194; called by muse, mutect2, varscan2
- ALG12 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | PolyPhen possibly damaging (0.882); catalogued as rs769555808; called by muse, mutect2, varscan2
- ALG13 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); catalogued as rs756868458, COSV99321992; called by muse, mutect2, varscan2
- ALG3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs763104840; called by muse, mutect2, varscan2
- ALG6 | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.108); catalogued as COSV54763105; called by muse, mutect2, varscan2
- ALLC | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1329886148; called by muse, mutect2, varscan2
- ALOX12 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV52349581; called by muse, mutect2, varscan2
- ALOX12 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs769590930; called by muse, mutect2, varscan2
- ALOX5 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV65553675; called by muse, varscan2
- ALOX5 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs753702775, COSV65554058; called by muse, mutect2, varscan2
- ALPG | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.739); catalogued as rs368869875; called by mutect2, varscan2
- ALS2CL | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs373261377; called by muse, mutect2, varscan2
- AMDHD1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57139184; called by muse, varscan2
- AMER1 | c.2540A>C p.H847P | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV57658955; called by muse, mutect2, varscan2
- AMER2 | c.1763C>A p.S588Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100766365; called by muse, mutect2, varscan2
- AMIGO2 | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.091); catalogued as rs139663398; called by muse, mutect2, varscan2
- AMOTL1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.098); catalogued as rs371806495, COSV54414848; called by mutect2, varscan2
- AMOTL1 | c.2144C>T p.T715M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs535040317; called by muse, mutect2, varscan2
- AMOTL2 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs775118618, COSV51438677; called by muse, mutect2, varscan2
- AMOTL2 | c.1862G>A p.R621K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.114); catalogued as rs747935308, COSV99850603; called by muse, mutect2
- AMY2B | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs150795802; called by muse, mutect2, varscan2
- ANAPC1 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs1395898147; called by muse, mutect2, varscan2
- ANK2 | c.3031C>T p.R1011C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1226180418, COSV52163529; called by muse, mutect2, varscan2
- ANK3 | c.4381G>A p.A1461T (on ENST00000280772 / NM_001320874.2; = p.A586T on NM_001149.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.288); catalogued as rs373826882; called by muse, mutect2, varscan2
- ANKEF1 | c.1185C>A p.F395L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65693464, COSV65693718; called by muse, mutect2, varscan2
- ANKMY1 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs148452586, COSV56033711; called by muse, mutect2, varscan2
- ANKRD17 | c.7319C>T p.T2440M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs770029425, COSV58230227; called by muse, mutect2, varscan2
- ANKRD23 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as rs141023516, COSV58413178; called by muse, mutect2, varscan2
- ANKRD27 | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs757626430; called by muse, mutect2, varscan2
- ANKRD34B | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs926351132; called by muse, mutect2
- ANKRD44 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764702362, COSV56552819; called by muse, mutect2, varscan2
- ANKRD50 | c.3037C>T p.R1013C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145805142, COSV72386026; called by muse, mutect2, varscan2
- ANKRD50 | c.2714A>G p.N905S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.027); catalogued as rs1487774504; called by muse, mutect2, varscan2
- ANKRD52 | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.107); catalogued as rs978832958, COSV57283640; called by muse, varscan2
- ANKRD52 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768397824, COSV57282216; called by muse, mutect2, varscan2
- ANKS1B | c.1349A>G p.N450S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV101612644; called by muse, mutect2, varscan2
- ANO4 | c.325G>A p.G109R (on ENST00000392977 / NM_001286615.2; = p.G74R on NM_178826.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV54594038; called by muse, mutect2, varscan2
- ANO5 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61088911, COSV61091584; called by muse, mutect2, varscan2
- ANO7 | c.1006C>T p.R336C (on ENST00000274979; = p.R282C on NM_001370694.2) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as rs369123528; called by muse, varscan2
- ANO9 | c.1287C>A p.F429L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1205047578, COSV60452093; called by muse, mutect2, varscan2
- ANO9 | c.833-1G>T p.X278_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV60450168; called by muse, mutect2
- ANXA6 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs748400306, COSV62908167; called by muse, mutect2, varscan2
- AOC1 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs766971033, COSV62868602, COSV62870832; called by muse, mutect2, varscan2
- AOC2 | c.1600T>C p.W534R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.976); catalogued as rs1313445493; called by muse, mutect2, varscan2
- AP002512.3 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV99688202; called by muse, mutect2
- AP1G2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs753114510; called by muse, mutect2, varscan2
- AP2A1 | c.2864G>A p.R955Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1229379406; called by muse, mutect2, varscan2
- AP3B2 | c.2082C>T p.D694= | Splice Region (SNP) | VAF 15/58 reads (26%) | catalogued as rs1345840572; called by muse, mutect2, varscan2
- AP3B2 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752418242; called by mutect2, varscan2
- APAF1 | c.2780A>G p.D927G (on ENST00000551964 / NM_181861.2; = p.D873G on NM_001160.3) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV59668441; called by muse, mutect2, varscan2
- APBA1 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367760423; called by muse, mutect2, varscan2
- APBA1 | c.1222T>C p.S408P | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV55221809; called by muse, mutect2, varscan2
- APBA1 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs201072152, COSV55221103; called by muse, mutect2, varscan2
- APBA1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs564159274, COSV55232051; called by muse, varscan2
- APBB1 | c.143A>C p.K48T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); catalogued as rs1453358189; called by muse, mutect2, varscan2
- APC | c.8264C>A p.S2755Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.452); catalogued as COSV99965916; called by muse, mutect2, varscan2
- APEX2 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs764409927, COSV58193466; called by muse, mutect2, varscan2
- APOA5 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as rs143382500; called by muse, varscan2
- APOB | c.8596A>G p.T2866A | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV51950039; called by muse, mutect2, varscan2
- APOB | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769425660, COSV51938544; called by muse, mutect2, varscan2
- APOH | c.856T>A p.F286I | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.255); catalogued as COSV52772237; called by muse, mutect2, varscan2
- APOL2 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.133); catalogued as rs760928601, COSV50772910; called by muse, mutect2, varscan2
- APOO | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as rs373029808, COSV101004914; called by muse, mutect2, varscan2
- APPL1 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.259); catalogued as rs199533180; called by muse, mutect2, varscan2
- APRT | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs752166198, COSV51940987; called by muse, mutect2, varscan2
- AQP1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs375226621; called by mutect2, varscan2
- AQP6 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs779784128; called by muse, mutect2, varscan2
- AR | c.2479T>A p.F827I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.911); catalogued as COSV65965212; called by muse, mutect2, varscan2
- ARAP2 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs34611360; called by muse, mutect2, varscan2
- AREL1 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs375993687; called by muse, mutect2, varscan2
- ARF4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); catalogued as rs778744712, COSV57715182; called by muse, varscan2
- ARFGEF1 | c.3836T>C p.F1279S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99142468; called by muse, mutect2, varscan2
- ARFGEF1 | c.3458A>G p.D1153G | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs955116586; called by muse, varscan2
- ARG2 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as rs746310852; called by muse, mutect2, varscan2
- ARHGAP1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1341316225; called by muse, mutect2, varscan2
- ARHGAP10 | c.687G>T p.Q229H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100331315; called by muse, mutect2, varscan2
- ARHGAP20 | c.841T>G p.S281A | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.289); catalogued as rs1382162868; called by muse, mutect2, varscan2
- ARHGAP26 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs761574373, COSV99191091; called by muse, mutect2, varscan2
- ARHGAP32 | c.2590C>T p.P864S (on ENST00000310343 / NM_001378025.1; = p.P515S on NM_014715.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100087478; called by muse, mutect2, varscan2
- ARHGAP39 | c.3046C>T p.R1016C (on ENST00000276826 / NM_001308208.2; = p.R1047C on NM_025251.2) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs149589076, COSV99431874; called by muse, mutect2, varscan2
- ARHGAP39 | c.2528C>T p.A843V (on ENST00000276826 / NM_001308208.2; = p.A874V on NM_025251.2) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1334771312, COSV52769615; called by muse, mutect2, varscan2
- ARHGAP39 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs777473259; called by muse, mutect2, varscan2
- ARHGEF11 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs780005478, COSV59353176; called by mutect2, varscan2
- ARHGEF12 | c.2854G>T p.E952* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100754915, COSV100755034; called by muse, mutect2, varscan2
- ARHGEF16 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760848608; called by muse, mutect2, varscan2
- ARHGEF17 | c.1613C>T p.T538I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs758432120; called by muse, mutect2, varscan2
- ARHGEF19 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV54619011, COSV99579943; called by muse, mutect2, varscan2
- ARHGEF26 | c.2538G>T p.K846N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV62843723; called by muse, mutect2, varscan2
- ARHGEF28 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as rs779364770, COSV55252872; called by muse, varscan2
- ARHGEF28 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs369842264; called by muse, mutect2, varscan2
- ARHGEF37 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs777212007; called by muse, mutect2, varscan2
- ARID1B | c.5933C>T p.A1978V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs763660892; called by muse, mutect2, varscan2
- ARIH2 | c.1244A>G p.K415R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs918121667; called by muse, mutect2, varscan2
- ARL11 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs1301834194; called by muse, mutect2, varscan2
- ARL11 | c.530G>T p.S177I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as COSV56290771; called by muse, mutect2, varscan2
- ARMC12 | c.309G>A p.E103= (on ENST00000373866 / NM_001286574.2; = p.E130= on NM_145028.5) | Splice Region (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99849552; called by muse, varscan2
- ARMC4 | c.1955T>C p.V652A | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs1228503693; called by muse, mutect2, varscan2
- ARMC5 | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as rs1379678857; called by muse, mutect2, varscan2
- ARMH4 | c.1235T>C p.V412A | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as rs1323914138; called by muse, mutect2, varscan2
- ARNT | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752945065, COSV62230960; called by muse, mutect2, varscan2
- ARNT2 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV100308956; called by muse, mutect2, varscan2
- ARPC1A | c.983+1G>A p.X328_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as rs1385482184; called by muse, mutect2
- ARRDC3 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV99475132; called by muse, mutect2, varscan2
- ART4 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.026); catalogued as rs142165195; called by mutect2, varscan2
- ARX | c.998C>T p.T333I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as CM040210, CM133522; called by muse, mutect2, varscan2
- ASAH1 | c.354T>C p.P118= | Splice Region (SNP) | VAF 9/35 reads (26%) | catalogued as rs184908516; called by muse, mutect2, varscan2
- ASB12 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs201303910; called by muse, mutect2, varscan2
- ASB16 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs368482999; called by muse, mutect2, varscan2
- ASCC2 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779333751; called by muse, mutect2, varscan2
- ASCC3 | c.5249C>T p.A1750V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.566); catalogued as COSV64978513; called by muse, mutect2, varscan2
- ASCC3 | c.2801G>A p.G934D | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61226199; called by muse, mutect2, varscan2
- ASCC3 | c.938T>A p.I313N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs751120994, COSV61226556; called by muse, mutect2, varscan2
- ASCC3 | c.533A>C p.H178P | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs768052591; called by muse, mutect2, varscan2
- ASGR2 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54689537; called by muse, mutect2, varscan2
- ASH1L | c.8287G>A p.D2763N (on ENST00000368346 / NM_001366177.2; = p.D2758N on NM_018489.3) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64211610; called by muse, mutect2, varscan2
- ASH1L | c.5947C>T p.R1983C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1232564099; called by muse, mutect2, varscan2
- ASIC5 | c.701A>G p.N234S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.213); catalogued as rs758176544; called by muse, mutect2, varscan2
- ASL | c.1079T>C p.M360T | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs875989948, CM016276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASMTL | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs200185423, COSV67243413; called by muse, mutect2, varscan2
- ASNSD1 | c.1846dup p.I616Nfs*2 | Frame Shift Ins (INS) | VAF 14/55 reads (25%) | catalogued as rs758014819; called by mutect2, pindel, varscan2
- ASPM | c.8619G>A p.W2873* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as rs929564037; called by muse, mutect2, varscan2
- ASPM | c.4214G>A p.R1405H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs143092798, COSV54141357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPM | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs199422128; ClinVar: benign; called by muse, mutect2, varscan2
- ASS1 | c.978G>A p.W326* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV61691095; called by muse, mutect2, varscan2
- ASXL3 | c.5020G>A p.E1674K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as rs770577167, COSV52461969, COSV99327010; called by muse, varscan2
- ASXL3 | c.5081C>T p.P1694L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs377243058; called by muse, varscan2
- ATAD2 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as rs1429466956; called by muse, mutect2, varscan2
- ATAD3A | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs757888186; called by muse, mutect2, varscan2
- ATAT1 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs151162327; called by muse, mutect2
- ATF6 | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as rs889228888, COSV63406457; called by muse, mutect2, varscan2
- ATF7IP | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1409123142, COSV53778159; called by muse, mutect2, varscan2
- ATF7IP2 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs767736915, COSV61092144; called by muse, mutect2, varscan2
- ATG10 | c.31dup p.T11Nfs*11 | Frame Shift Ins (INS) | VAF 17/71 reads (24%) | catalogued as rs1561240847; called by mutect2, pindel, varscan2
- ATG13 | c.1379C>T p.P460L (on ENST00000359513 / NM_001346321.1; = p.P423L on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763642397; called by muse, mutect2, varscan2
- ATG9B | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs377299879; called by muse, mutect2, varscan2
- ATM | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as rs201780199, COSV53773409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.4400C>T p.A1467V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as rs771012252, COSV63520994; called by mutect2, varscan2
- ATP10A | c.2596C>T p.R866C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781169989, COSV63518475; called by muse, mutect2, varscan2
- ATP10A | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as rs267604144, COSV63512941; called by muse, mutect2, varscan2
- ATP10B | c.2699C>T p.T900M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766661717; called by muse, varscan2
- ATP10B | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs754306962; called by muse, mutect2, varscan2
- ATP11A | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372436282, COSV52115092; called by muse, mutect2, varscan2
- ATP11B | c.1877G>T p.R626I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60034269; called by muse, mutect2, varscan2
- ATP11C | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100558025; called by muse, mutect2, varscan2
- ATP13A1 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV52291269; called by muse, mutect2, varscan2
- ATP1A2 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs760155608, COSV63405678; called by muse, mutect2, varscan2
- ATP1A2 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1274611333, COSV63404080; called by muse, mutect2, varscan2
- ATP1A3 | c.2881C>A p.L961M (on ENST00000545399 / NM_001256214.2; = p.L948M on NM_152296.5) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV57491546; called by muse, mutect2, varscan2
- ATP1A3 | c.2515C>T p.P839S (on ENST00000545399 / NM_001256214.2; = p.P826S on NM_152296.5) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100132123; called by muse, mutect2, varscan2
- ATP1A4 | c.2521C>T p.L841F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as rs1409576907, COSV63626424; called by muse, mutect2, varscan2
- ATP2A2 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs767974635; called by muse, mutect2, varscan2
- ATP2B2 | c.3340C>T p.R1114W (on ENST00000352432; = p.R1080W on NM_001683.5) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1457719867; called by muse, mutect2, varscan2
- ATP2C2 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765718239, COSV52293308; called by muse, mutect2, varscan2
- ATP5F1B | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.825); catalogued as rs778911180, COSV51634667; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2267T>G p.L756R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100377076; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs998295281; called by muse, mutect2, varscan2
- ATP7B | c.1760C>T p.T587M | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs757716093, COSV54439725; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP8B3 | c.3881C>T p.S1294L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs764922106, COSV59543438, COSV59546748; called by muse, mutect2, varscan2
- ATP9A | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750918611; called by muse, mutect2, varscan2
- ATP9A | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194861517, COSV58762840, COSV58770385; called by muse, mutect2, varscan2
- ATP9B | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.14); catalogued as rs779272517, COSV56947649; called by muse, varscan2
- ATR | c.3934T>C p.Y1312H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV100638563; called by muse, mutect2, varscan2
- ATRAID | c.529C>A p.L177M (on ENST00000611786; = p.L64M on NM_016085.5) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.741); catalogued as COSV53029203; called by muse, mutect2, varscan2
- ATRN | c.3086C>T p.S1029L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs535390217; called by mutect2, varscan2
- ATRNL1 | c.4126G>T p.G1376* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100372000, COSV58080371; called by muse, mutect2, varscan2
- ATRX | c.128A>G p.N43S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64869521; called by muse, mutect2, varscan2
- AWAT2 | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.381); catalogued as COSV99339658; called by muse, mutect2, varscan2
- AXL | c.2300G>A p.R767H (on ENST00000301178 / NM_021913.5; = p.R758H on NM_001699.6) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200271277; called by muse, varscan2
- B3GALT2 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.333); catalogued as rs752275297, COSV104427328, COSV66463885; called by muse, mutect2, varscan2
- B3GNT4 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1343771370, COSV57337159; called by muse, mutect2, varscan2
- B3GNT7 | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1384001985; called by muse, mutect2, varscan2
- B4GALT5 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406837691, COSV65493257; called by muse, mutect2, varscan2
- B4GALT7 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV99218999; called by muse, mutect2, varscan2
- B4GAT1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs1188082765, COSV60820157; called by muse, mutect2, varscan2
- BAG5 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs771563413; called by muse, mutect2, varscan2
- BAHCC1 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as rs782682025; called by muse, mutect2, varscan2
- BAHD1 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs777535263, COSV69083924; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs747446690, COSV99133782; called by muse, mutect2
- BAIAP3 | c.881+1G>A p.X294_splice | Splice Site (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100181658; called by muse, varscan2
- BANP | c.279G>T p.Q93H (on ENST00000286122; = p.Q101H on NM_017869.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99620358; called by muse, mutect2, varscan2
- BANP | c.1097C>T p.P366L (on ENST00000286122; = p.P335L on NM_017869.4) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.241); catalogued as rs1312556213, COSV53738732; called by muse, mutect2, varscan2
- BAZ1A | c.3493C>A p.L1165I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62412271; called by muse, mutect2, varscan2
- BAZ2A | c.3485C>T p.A1162V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs563039958, COSV51643821; called by mutect2, varscan2
- BAZ2A | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 36/111 reads (32%) | catalogued as COSV51644587; called by muse, mutect2, varscan2
- BAZ2B | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs1300707163; called by muse, mutect2, varscan2
- BBS9 | c.1799G>A p.R600H (on ENST00000242067 / NM_001348036.1; = p.R560H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749018243, COSV54189065; called by muse, varscan2
- BBS9 | c.1856G>A p.R619H (on ENST00000242067 / NM_001348036.1; = p.R579H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750412402; called by muse, varscan2
- BCAR1 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs568726629, COSV50797034; called by muse, mutect2, varscan2
- BCAR3 | c.2063G>T p.S688I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.499); catalogued as COSV53078841; called by muse, mutect2, varscan2
- BCL11A | c.1163G>A p.R388H (on ENST00000335712 / NM_001365609.1; = p.R422H on NM_018014.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59633472; called by muse, varscan2
- BCL2L11 | c.562C>T p.R188C (on ENST00000393256 / NM_138621.5; = p.R128C on NM_006538.5) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs765527733; called by muse, varscan2
- BCL2L13 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.009); catalogued as rs139273724; called by muse, mutect2, varscan2
- BCLAF1 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as rs201040875; called by mutect2, varscan2
- BCORL1 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54400613; called by muse, mutect2, varscan2
- BCORL1 | c.3603G>T p.E1201D | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54394573; called by muse, mutect2, varscan2
- BDKRB1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs573449408, COSV53706364; called by muse, varscan2
- BDKRB2 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as COSV60016626; called by muse, mutect2, varscan2
- BEND5 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.984); catalogued as rs549852138; called by muse, mutect2, varscan2
- BFAR | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs547915921, COSV99902081; called by muse, mutect2, varscan2
- BFSP1 | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs751346192; called by muse, mutect2, varscan2
- BHLHE22 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1357389081; called by muse, mutect2, varscan2
- BIRC6 | c.12206C>T p.S4069L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66042968; called by muse, mutect2, varscan2
- BIRC6 | c.14017T>C p.W4673R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101428285; called by muse, mutect2, varscan2
- BLM | c.3757T>G p.L1253V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as rs1249288071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BLNK | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs782667010, COSV56412399; called by muse, varscan2
- BMP10 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs537354595; called by muse, varscan2
- BMP2K | c.2616G>T p.Q872H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99784691; called by muse, mutect2, varscan2
- BMP7 | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs746092842; called by muse, mutect2, varscan2
- BMPR2 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs771887212; called by muse, mutect2, varscan2
- BOD1L1 | c.9070C>T p.R3024C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369852170; called by muse, mutect2, varscan2
- BOD1L1 | c.2866C>T p.R956C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs201454538; called by muse, mutect2, varscan2
- BOK | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs374419286; called by muse, mutect2, varscan2
- BPGM | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs771037885, COSV61324703; called by mutect2, varscan2
- BPGM | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1206399907, COSV100790224; called by muse, mutect2, varscan2
- BPIFB1 | c.1402C>A p.L468I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV99487394; called by muse, mutect2
- BPIFC | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs376981555; called by muse, mutect2, varscan2
- BRAP | c.375G>T p.Q125H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58163742; called by muse, varscan2
- BRAT1 | c.1480A>G p.I494V | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61397259; called by muse, mutect2, varscan2
- BRCA1 | c.3082C>T p.R1028C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as rs80357049, COSV58788564; ClinVar: conflicting interpretations of pathogenicity / benign / likely benign; called by muse, mutect2, varscan2
- BRCA1 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1555596362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.8825C>T p.A2942V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373227180, COSV101204728; ClinVar: uncertain significance; called by muse, varscan2
- BRCC3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV57462323; called by muse, mutect2, varscan2
- BRD1 | c.3037G>A p.E1013K (on ENST00000216267 / NM_001349940.1; = p.E1144K on NM_001304808.3) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1046139158, COSV53462584; called by muse, mutect2, varscan2
- BRD1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as rs777684239; called by muse, varscan2
- BRD3 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV57705561; called by mutect2, varscan2
- BRINP2 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763172017, COSV64175944; called by muse, mutect2, varscan2
- BRSK2 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.418); catalogued as rs773917255; called by muse, mutect2, varscan2
- BRWD1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60894280; called by muse, mutect2, varscan2
- BRWD3 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100955693; called by muse, mutect2, varscan2
- BTAF1 | c.4814C>A p.S1605Y | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56434153; called by muse, mutect2, varscan2
- BTAF1 | c.5152G>A p.A1718T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564727860; called by muse, mutect2, varscan2
- BTBD1 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1378157350; called by muse, mutect2, varscan2
- BTN2A1 | c.1293C>A p.Y431* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as rs748215931; called by muse, mutect2, varscan2
- BTN3A3 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as rs372313829, COSV55071255; called by muse, mutect2, varscan2
- BUB1B | c.293T>C p.M98T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1446063325; called by muse, mutect2, varscan2
- BUB1B | c.2792G>A p.R931Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.936); catalogued as rs751509832; ClinVar: uncertain significance; called by muse, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs751388819; called by mutect2, varscan2
- C10orf90 | c.1310C>A p.A437D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52955357; called by muse, mutect2, varscan2
- C12orf42 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV59381973; called by muse, mutect2, varscan2
- C12orf43 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56566996; called by muse, mutect2, varscan2
- C12orf65 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); catalogued as rs777262448, COSV99473869; called by muse, mutect2, varscan2
- C14orf39 | c.511+1G>T p.X171_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV58784176; called by muse, mutect2, varscan2
- C15orf39 | c.2753G>A p.R918H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs150058666; called by muse, mutect2, varscan2
- C16orf71 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs781046898; called by muse, mutect2, varscan2
- C16orf92 | c.366C>A p.F122L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as rs372283454; called by muse, mutect2, varscan2
- C18orf25 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754564079, COSV56368145, COSV56368630; called by muse, mutect2, varscan2
- C18orf25 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99960159; called by muse, mutect2, varscan2
- C1QTNF1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs758961252, COSV59263078; called by muse, varscan2
- C1R | c.1873C>T p.R625C (on ENST00000536053 / NM_001354346.2; = p.R611C on NM_001733.7) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs772664204, COSV101605606; called by muse, mutect2, varscan2
- C1R | c.1498C>T p.R500C (on ENST00000536053 / NM_001354346.2; = p.R486C on NM_001733.7) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV73383057; called by muse, varscan2
- C1orf112 | c.2005A>G p.M669V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs913975669; called by muse, mutect2, varscan2
- C1orf116 | c.833C>A p.A278D | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV63944721; called by muse, mutect2, varscan2
- C1orf116 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.258); catalogued as rs750810187; called by muse, mutect2, varscan2
- C2CD2L | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1362547738, COSV60884089; called by muse, mutect2, varscan2
- C2CD6 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53799304; called by muse, varscan2
- C2orf16 | c.4325G>T p.R1442I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV62675432; called by muse, mutect2, varscan2
- C2orf80 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs987661802, COSV58015332; called by muse, varscan2
- C5orf38 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs779809202, COSV57409721; called by muse, mutect2, varscan2
- C7 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.122); catalogued as rs1561253223, COSV57475677; called by muse, mutect2, varscan2
- C7orf31 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as COSV52221099; called by muse, mutect2, varscan2
- C7orf33 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs759489205, COSV61023126, COSV61023884; called by muse, varscan2
- C7orf57 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs770795124, COSV100817201; called by muse, mutect2, varscan2
- C8orf34 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.178); catalogued as COSV57398531; called by muse, mutect2, varscan2
- C8orf58 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373734103, COSV99254423; called by muse, mutect2, varscan2
- C9orf64 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100123469; called by muse, mutect2, varscan2
- CABIN1 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs200579275, COSV99572893; called by muse, mutect2, varscan2
- CABP1 | c.763C>T p.R255C (on ENST00000316803 / NM_001033677.1; = p.R52C on NM_004276.5) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56457412; called by muse, mutect2, varscan2
- CACNA1A | c.5983C>T p.R1995C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs903596182; called by muse, mutect2, varscan2
- CACNA1C | c.4610G>A p.R1537H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1455468826, COSV100222098, COSV59738753; called by muse, mutect2, varscan2
- CACNA1D | c.1538G>A p.R513H (on ENST00000350061 / NM_001128840.3; = p.R533H on NM_000720.4) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1559570791, COSV55452065; called by muse, mutect2, varscan2
- CACNA1D | c.2053C>T p.R685W (on ENST00000350061 / NM_001128840.3; = p.R705W on NM_000720.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763320856; called by mutect2, varscan2
- CACNA1E | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV62406416; called by muse, mutect2, varscan2
- CACNA1E | c.3919G>A p.A1307T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs373085902; called by mutect2, varscan2
- CACNA1F | c.4768C>A p.Q1590K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM158406; called by muse, mutect2, varscan2
- CACNA1G | c.2860G>A p.V954M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375782901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1G | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1299101556; called by muse, mutect2
- CACNA1H | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61989251; called by muse, mutect2, varscan2
- CACNA1H | c.4753C>T p.R1585C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs764235503; called by muse, mutect2, varscan2
- CACNB2 | c.1433G>A p.R478H (on ENST00000324631 / NM_201596.3; = p.R423H on NM_000724.4) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs781646326, COSV56622648; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs866575214, COSV55633760; called by muse, mutect2, varscan2
- CADM2 | c.536G>A p.R179H (on ENST00000407528 / NM_001167674.2; = p.R181H on NM_153184.4) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs1416693838, COSV67356966, COSV67406817; called by muse, mutect2, varscan2
- CADM3 | c.954C>T p.D318= (on ENST00000368125 / NM_001127173.3; = p.D352= on NM_021189.5) | Splice Region (SNP) | VAF 13/21 reads (62%) | catalogued as rs374461427; called by muse, mutect2, varscan2
- CADPS | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs774721337; called by muse, varscan2
- CALCRL | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201789608, COSV66473826; called by muse, mutect2, varscan2
- CALHM5 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100635648; called by muse, mutect2, varscan2
- CAMSAP1 | c.1862G>T p.R621M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV56727705; called by muse, mutect2, varscan2
- CAMSAP2 | c.126A>C p.K42N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV52672384; called by muse, mutect2, varscan2
- CAMSAP2 | c.2251C>T p.R751W (on ENST00000236925 / NM_001297707.2; = p.R740W on NM_203459.3) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1301967760, COSV99373044; called by muse, mutect2, varscan2
- CAMSAP2 | c.3127G>T p.E1043* (on ENST00000236925 / NM_001297707.2; = p.E1032* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV52668141; called by muse, varscan2
- CAMTA1 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.355); catalogued as rs777391693, COSV57879657; called by muse, mutect2, varscan2
- CAPN12 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs776565451, COSV61016468; called by muse, mutect2, varscan2
- CAPN13 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208776768; called by muse, mutect2, varscan2
- CAPN15 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs375530346; called by muse, mutect2, varscan2
- CAPN2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1383416012; called by muse, mutect2, varscan2
- CAPN5 | c.1483C>T p.R495C (on ENST00000456580; = p.R455C on NM_004055.5) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs370387285; called by muse, varscan2
- CAPN5 | c.1562G>A p.G521D (on ENST00000456580; = p.G481D on NM_004055.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs782027905, COSV53686220; called by muse, varscan2
- CAPN9 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201859022, COSV99681187; called by muse, mutect2, varscan2
- CARD11 | c.3229C>T p.R1077W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV67799760; called by muse, mutect2, varscan2
- CARD11 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62754862; called by muse, mutect2, varscan2
- CARD11 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1161484391; called by muse, mutect2, varscan2
- CARD6 | c.2237C>A p.S746Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.819); catalogued as COSV54569007; called by muse, varscan2
- CARMIL1 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1485394555; called by muse, mutect2, varscan2
- CARMIL3 | c.3613C>T p.P1205S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs1333737582; called by muse, mutect2, varscan2
- CARNS1 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs774158852, COSV57132101; called by muse, mutect2, varscan2
- CARNS1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.719); catalogued as rs570844079; called by muse, mutect2, varscan2
- CARS2 | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV57284144; called by muse, mutect2, varscan2
- CASK | c.1523A>T p.N508I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100587038; called by muse, mutect2, varscan2
- CASP8 | c.936C>A p.C312* (on ENST00000432109 / NM_033355.3; = p.C329* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV51858326; called by muse, mutect2, varscan2
- CASP8 | c.1313A>G p.D438G (on ENST00000432109 / NM_033355.3; = p.D455G on NM_001228.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99629668, COSV99630738; called by muse, mutect2, varscan2
- CASP8AP2 | c.2356T>C p.F786L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99387361; called by muse, mutect2, varscan2
- CASP8AP2 | c.3611A>G p.H1204R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.051); catalogued as rs1205882156; called by muse, mutect2, varscan2
- CASQ1 | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.442); catalogued as COSV63624531; called by muse, mutect2, varscan2
- CASQ2 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV54771951; called by muse, mutect2, varscan2
- CASS4 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs1280406712, COSV64387198; called by muse, mutect2, varscan2
- CAST | c.371C>T p.P124L (on ENST00000341926; = p.P207L on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs763856934; called by muse, mutect2, varscan2
- CBLB | c.2487G>T p.R829S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs776863118, COSV51434485; called by muse, mutect2, varscan2
- CC2D1B | c.764-1G>A p.X255_splice | Splice Site (SNP) | VAF 16/54 reads (30%) | catalogued as rs1159283824, COSV52560088; called by muse, varscan2
- CCDC106 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1342673037; called by muse, mutect2, varscan2
- CCDC106 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV58276005; called by muse, mutect2, varscan2
- CCDC110 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as rs777082668, COSV104409873; called by mutect2, varscan2
- CCDC114 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs761311942; called by muse, mutect2, varscan2
- CCDC114 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.09); catalogued as rs772349661, COSV59555205; called by muse, mutect2, varscan2
- CCDC120 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs373836567; called by muse, varscan2
- CCDC136 | c.2399A>G p.Y800C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52805541; called by muse, mutect2, varscan2
- CCDC137 | c.235A>G p.N79D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV61303160; called by mutect2, varscan2
- CCDC141 | c.1960G>T p.E654* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV55368066; called by muse, varscan2
- CCDC146 | c.1064G>T p.R355I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV53544247; called by muse, mutect2, varscan2
- CCDC151 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV62699039; called by muse, varscan2
- CCDC171 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as rs746749844; called by muse, mutect2, varscan2
- CCDC189 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as rs535279129; called by muse, mutect2, varscan2
- CCDC191 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374764425; called by muse, mutect2, varscan2
- CCDC42 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs1166135536, COSV53449694; called by mutect2, varscan2
- CCDC47 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755476973, COSV56724607; called by muse, mutect2, varscan2
- CCDC63 | c.1625A>G p.E542G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.219); catalogued as COSV99960571; called by muse, mutect2, varscan2
- CCDC69 | c.365C>A p.S122Y | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1374064430, COSV62599841, COSV62600810; called by muse, mutect2, varscan2
- CCDC74B | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV60102065; called by muse, mutect2, varscan2
- CCDC78 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV99285117; called by muse, varscan2
- CCDC80 | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52819070; called by muse, mutect2, varscan2
- CCDC86 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769571200, COSV57124578; called by mutect2, varscan2
- CCDC88B | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.522); catalogued as COSV57266880; called by muse, mutect2, varscan2
- CCDC88C | c.3655C>T p.R1219C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs374425216; called by muse, mutect2, varscan2
- CCDC93 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765217420, COSV60124074; called by muse, mutect2, varscan2
- CCDC93 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs151101188; called by muse, varscan2
- CCDC9B | c.1528G>T p.G510* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs1301320371, COSV66875022; called by muse, mutect2, varscan2
- CCHCR1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145851882; called by muse, mutect2, varscan2
- CCIN | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as rs776121301; called by muse, mutect2, varscan2
- CCKBR | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV58098388; called by muse, mutect2
- CCL3L3 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 52/340 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1249997768; called by muse, varscan2
- CCN4 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758360129, COSV51534225; called by muse, mutect2, varscan2
- CCNA1 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs767692772; called by muse, mutect2, varscan2
- CCNB3 | c.1698G>T p.E566D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as COSV52072687; called by muse, mutect2, varscan2
- CCNB3 | c.3423+1G>A p.X1141_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99329996; called by muse, mutect2, varscan2
- CCNH | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs763000210; called by muse, mutect2, varscan2
- CCNI2 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as COSV66394383; called by muse, mutect2, varscan2
- CCR2 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.2); catalogued as rs1355689842; called by muse, mutect2, varscan2
- CCT5 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs998269335, COSV54724191; called by muse, mutect2, varscan2
- CCT6B | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV58488681; called by muse, mutect2, varscan2
- CCT8L2 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV63461624, COSV63463703; called by muse, mutect2, varscan2
- CCZ1B | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs764721779, COSV57436035; called by muse, mutect2, varscan2
- CD101 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759778037, COSV56716434; called by muse, mutect2, varscan2
- CD19 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs750825735, COSV104410525; called by muse, mutect2, varscan2
- CD1C | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV63805793; called by muse, mutect2, varscan2
- CD1D | c.996G>T p.Q332H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV63809134; called by muse, mutect2, varscan2
- CD2 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs772447791, COSV65644759; called by mutect2, varscan2
- CD200R1L | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs374244518; called by muse, mutect2, varscan2
- CD276 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as rs776412054, COSV59203320; called by muse, mutect2, varscan2
- CD300C | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.109); catalogued as rs777598876; called by muse, mutect2, varscan2
- CD34 | c.997A>C p.N333H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs753507818; called by muse, mutect2
- CD3G | c.347C>A p.S116Y | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV52674686; called by muse, mutect2, varscan2
- CD5L | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs527891722, COSV100941035, COSV63821950, COSV63822464; called by muse, varscan2
- CD80 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.134); catalogued as rs267599556; called by muse, mutect2, varscan2
- CD93 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV99848987; called by muse, mutect2, varscan2
- CD99 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs948629582; called by muse, mutect2, varscan2
- CDAN1 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs141007889; called by muse, mutect2, varscan2
- CDC20B | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57051218; called by muse, mutect2, varscan2
- CDC27 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as rs77685276; called by muse, mutect2, varscan2
- CDC42BPG | c.4024G>A p.V1342M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61347852; called by muse, mutect2, varscan2
- CDC45 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs371699135; called by muse, mutect2, varscan2
- CDC6 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs4135016; called by muse, mutect2, varscan2
- CDCA2 | c.2212G>T p.E738* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as rs1293914434, COSV100399076; called by muse, mutect2
- CDCA2 | c.2528A>G p.H843R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs922692856; called by muse, mutect2, varscan2
- CDCA7 | c.313G>A p.D105N (on ENST00000347703 / NM_145810.3; = p.D184N on NM_031942.5) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV60721934; called by muse, mutect2
- CDH1 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs556110297, COSV99028475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH1 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs142927667; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.388); catalogued as rs770889275, COSV52572277, COSV52589543; called by muse, mutect2, varscan2
- CDH11 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as rs770554222; called by muse, varscan2
- CDH12 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101203417; called by muse, mutect2, varscan2
- CDH18 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1315166062; called by muse, mutect2, varscan2
- CDH18 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56940536; called by muse, mutect2, varscan2
- CDH18 | c.4A>G p.K2E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99934368; called by muse, mutect2, varscan2
- CDH24 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52982759; called by muse, varscan2
- CDH5 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58520261; called by muse, mutect2, varscan2
- CDH5 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as rs375751151; called by muse, mutect2, varscan2
- CDHR3 | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs368274712; called by muse, mutect2, varscan2
- CDK11A | c.553C>T p.R185W (on ENST00000378633 / NM_001313896.2; = p.R195W on NM_024011.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs767793604; called by muse, mutect2, varscan2
- CDK11B | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.915); catalogued as rs1355162260, COSV52363376; called by muse, mutect2, varscan2
- CDK18 | c.728G>A p.R243Q (on ENST00000506784 / NM_212503.3; = p.R213Q on NM_002596.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs776804607, COSV63727273; called by muse, mutect2, varscan2
- CDK6 | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV99721258; called by muse, mutect2, varscan2
- CDK7 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as rs1231179576; called by muse, mutect2, varscan2
- CDX2 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs763139212, COSV66829422; called by muse, mutect2, varscan2
- CDYL2 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.693); catalogued as rs1348845116; called by muse, mutect2, varscan2
- CEACAM18 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.092); catalogued as rs200740909; called by muse, mutect2, varscan2
- CEACAM21 | c.850G>A p.G284S (on ENST00000401445 / NM_001098506.4; = p.G283S on NM_033543.6) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs199631079, COSV99079010; called by muse, mutect2, varscan2
- CELF3 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs940641224; called by muse, mutect2, varscan2
- CELF6 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as rs777427399; called by mutect2, varscan2
- CELSR1 | c.6499G>A p.E2167K | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761949438; called by muse, mutect2, varscan2
- CELSR2 | c.5128G>A p.G1710R | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as rs1036344220; called by muse, mutect2
- CELSR2 | c.6920G>A p.R2307H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.793); catalogued as rs199671594; called by muse, mutect2, varscan2
- CELSR2 | c.7527C>A p.D2509E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54768698; called by muse, mutect2, varscan2
- CEMIP2 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs746389869, COSV65488164; called by muse, mutect2, varscan2
- CENPB | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60148116; called by muse, mutect2, varscan2
- CENPC | c.1187G>T p.R396I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV99893948; called by muse, mutect2, varscan2
- CENPE | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV54383688; called by muse, mutect2, varscan2
- CENPI | c.982A>C p.S328R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV54505176; called by muse, mutect2, varscan2
- CEP126 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs372773838; called by muse, mutect2, varscan2
- CEP126 | c.1436G>A p.S479N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs766230867; called by muse, mutect2, varscan2
- CEP131 | c.1807C>T p.R603W (on ENST00000269392 / NM_001319228.2; = p.R600W on NM_014984.4) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150527009; called by muse, mutect2, varscan2
- CEP135 | c.422G>T p.R141I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV104435594; called by muse, mutect2
- CEP135 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs200040205; called by muse, mutect2, varscan2
- CEP152 | c.2995G>T p.E999* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100358454; called by muse, varscan2
- CEP162 | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750896447; called by muse, mutect2, varscan2
- CEP170 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100318124; called by muse, mutect2, varscan2
- CEP70 | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53879204; called by muse, mutect2, varscan2
- CEP70 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779132771, COSV53874100, COSV53877682; called by muse, mutect2, varscan2
- CEP70 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as rs751569983; called by muse, mutect2, varscan2
- CEP85 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as rs772525914; called by muse, mutect2, varscan2
- CEP89 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); catalogued as rs1163617366; called by muse, mutect2, varscan2
- CEPT1 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); catalogued as rs143162153; called by muse, mutect2, varscan2
- CEPT1 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1197932725, COSV62958662; called by muse, mutect2, varscan2
- CERCAM | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs374800255; called by muse, mutect2, varscan2
- CERS3 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs762930624; called by muse, mutect2, varscan2
- CERS4 | c.744C>A p.A248= | Splice Region (SNP) | VAF 19/119 reads (16%) | catalogued as COSV52166888; called by muse, varscan2
- CERS5 | c.836T>C p.V279A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as rs143505748; called by muse, mutect2, varscan2
- CES5A | c.831C>A p.F277L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV51865885; called by muse, mutect2
- CETP | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs750662640, COSV52363791; called by muse, mutect2, varscan2
- CFAP157 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs764305353; called by mutect2, varscan2
- CFAP251 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV56610461; called by muse, mutect2, varscan2
- CFAP251 | c.3236-1G>T p.X1079_splice | Splice Site (SNP) | VAF 35/109 reads (32%) | catalogued as COSV56609856; called by muse, mutect2, varscan2
- CFAP300 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1420836171, COSV71570996; called by mutect2, varscan2
- CFAP36 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV55407723; called by muse, mutect2, varscan2
- CFAP45 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as rs371524691; called by muse, mutect2, varscan2
- CFAP52 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as rs576284692, COSV100235573; called by muse, mutect2, varscan2
- CFAP61 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs371793125, COSV55639118; called by muse, mutect2, varscan2
- CFAP61 | c.1206G>A p.R402= | Splice Region (SNP) | VAF 33/113 reads (29%) | catalogued as rs771519008; called by muse, mutect2, varscan2
- CFAP61 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1392638077; called by muse, mutect2, varscan2
- CFAP69 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60189216; called by muse, mutect2, varscan2
- CFAP74 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758203916; called by muse, mutect2, varscan2
- CFDP1 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0.021); catalogued as COSV52207463; called by muse, mutect2, varscan2
- CFH | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs367932253; called by muse, mutect2, varscan2
- CFHR5 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.041); catalogued as rs753861647; called by muse, mutect2, varscan2
- CFLAR | c.877C>A p.L293I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV58580066, COSV58581331; called by muse, mutect2, varscan2
- CHD1 | c.3909G>T p.Q1303H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52341641; called by muse, mutect2, varscan2
- CHD1 | c.2089C>T p.R697* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV52339976, COSV52341314; called by muse, mutect2, varscan2
- CHD2 | c.5363G>A p.R1788H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs140365508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD3 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as rs749330456, COSV57876525; called by mutect2, varscan2
- CHD3 | c.4140G>A p.G1380= | Splice Region (SNP) | VAF 9/26 reads (35%) | catalogued as rs536279451; called by muse, mutect2, varscan2
- CHD3 | c.4408G>A p.G1470S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs769780640; called by muse, mutect2, varscan2
- CHD4 | c.3163C>T p.R1055C (on ENST00000357008 / NM_001363606.2; = p.R1068C on NM_001273.5) | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894255; called by muse, mutect2, varscan2
- CHD6 | c.7028C>T p.T2343M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs775912225; called by muse, mutect2, varscan2
- CHD6 | c.3836C>A p.A1279D | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.402); catalogued as COSV58559074, COSV58561084; called by muse, mutect2, varscan2
- CHD6 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.078); catalogued as rs556078000; called by muse, mutect2, varscan2
- CHD7 | c.7703G>A p.R2568Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.309); catalogued as rs369807016; called by muse, mutect2, varscan2
- CHD8 | c.5872C>A p.L1958M (on ENST00000646647 / NM_001170629.2; = p.L1679M on NM_020920.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.119); catalogued as COSV100765285; called by muse, mutect2, varscan2
- CHD9 | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV68296896; called by muse, mutect2, varscan2
- CHERP | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762120150, COSV99549963; called by muse, mutect2, varscan2
- CHGA | c.1004A>G p.E335G | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1394865669; called by muse, mutect2, varscan2
- CHGB | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as rs1363361159, COSV66761483; called by mutect2, varscan2
- CHKB | c.336C>T p.G112= | Splice Region (SNP) | VAF 8/27 reads (30%) | catalogued as rs1393144155, COSV56414806, COSV56418283; called by muse, mutect2, varscan2
- CHRD | c.2702G>A p.R901K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.186); catalogued as COSV52611793; called by muse, mutect2, varscan2
- CHRNA2 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs201370407, COSV53559172, COSV99532555; called by muse, mutect2, varscan2
- CHRNB4 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs771105669, COSV55717289, COSV99929256; called by muse, mutect2, varscan2
- CHST12 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.186); catalogued as rs769324562; called by muse, mutect2, varscan2
- CHST5 | c.255C>A p.H85Q | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1429588172; called by muse, mutect2, varscan2
- CHST6 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs376212281; called by muse, varscan2
- CHST6 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.054); catalogued as rs72547549, CM021970; called by muse, mutect2, varscan2
- CHTF18 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs868114535; called by muse, varscan2
- CHTF18 | c.2266G>T p.A756S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV99242775; called by muse, mutect2, varscan2
- CIDEC | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs774200069, COSV61061474; called by muse, mutect2, varscan2
- CILP | c.3299C>T p.S1100F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56027473; called by muse, mutect2, varscan2
- CILP2 | c.3181G>A p.V1061I | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375471099; called by muse, mutect2, varscan2
- CIP2A | c.2045T>C p.V682A | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1241694884; called by muse, mutect2, varscan2
- CIPC | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100694467; called by muse, mutect2, varscan2
- CIT | c.5974C>T p.R1992W | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs1482266127, COSV99949179; called by muse, mutect2, varscan2
- CIT | c.5464G>A p.D1822N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs368981957; called by muse, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as rs752250702; called by mutect2, varscan2
- CLASP2 | c.2350G>A p.G784S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs530462971; called by muse, mutect2
- CLASP2 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV56277715; called by muse, mutect2, varscan2
- CLASP2 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.107); catalogued as rs949174292, COSV100223673; called by muse, mutect2, varscan2
- CLCA4 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as rs762310034, COSV55367356; called by muse, mutect2, varscan2
- CLCA4 | c.2194C>T p.R732* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs751765325; called by muse, mutect2, varscan2
- CLCN2 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745848056; called by muse, mutect2, varscan2
- CLCN4 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV66469196; called by muse, mutect2, varscan2
- CLCN5 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as COSV56584830; called by muse, mutect2, varscan2
- CLDN10 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV65298443; called by muse, mutect2, varscan2
- CLDN22 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60109643; called by muse, mutect2, varscan2
- CLDN9 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745740390; called by muse, mutect2, varscan2
- CLEC16A | c.2543C>T p.T848I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs771877303; called by muse, varscan2
- CLEC16A | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761303559, COSV55492417; called by muse, varscan2
- CLEC18B | c.1113C>T p.I371= | Splice Region (SNP) | VAF 6/42 reads (14%) | catalogued as rs1263717026, COSV60577884; called by mutect2, varscan2
- CLEC3B | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770632684; called by muse, mutect2
- CLEC7A | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs759032825; called by mutect2, varscan2
- CLGN | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1234895824, COSV57774818; called by muse, varscan2
- CLINT1 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs771442603, COSV51623187; called by muse, mutect2, varscan2
- CLIP3 | c.1007A>G p.D336G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs1317419571; called by muse, mutect2, varscan2
- CLIP4 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs764347800, COSV60747867; called by muse, mutect2, varscan2
- CLMP | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as rs766246908; called by muse, mutect2, varscan2
- CLN3 | c.400G>A p.A134T (on ENST00000360019 / NM_001286104.2; = p.A158T on NM_000086.2) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.655); catalogued as rs386833723, CM052839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLN3 | c.346G>A p.V116I (on ENST00000360019 / NM_001286104.2; = p.V140I on NM_000086.2) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs373034150; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CLPB | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV53631752; called by muse, mutect2, varscan2
- CLPTM1 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.577); catalogued as rs899497370; called by muse, mutect2, varscan2
- CLSPN | c.305G>T p.R102M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52048686; called by muse, mutect2, varscan2
- CLTC | c.3584A>C p.N1195T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.672); catalogued as COSV99293031; called by muse, mutect2, varscan2
- CLVS2 | c.386G>T p.S129I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.505); catalogued as COSV51567045; called by muse, mutect2, varscan2
- CLVS2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.225); catalogued as rs752596301, COSV51558951; called by muse, mutect2, varscan2
- CMKLR1 | c.452G>A p.R151H (on ENST00000312143 / NM_001142344.2; = p.R149H on NM_004072.3) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771883601, COSV56437995; called by muse, mutect2, varscan2
- CMTM2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.146); catalogued as rs1186507113; called by muse, mutect2, varscan2
- CMTM3 | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV58062653; called by muse, mutect2, varscan2
- CMTM5 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs111290798; called by muse, mutect2, varscan2
- CMTR1 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs755381712, COSV100990852; called by muse, mutect2, varscan2
- CMYA5 | c.2579C>T p.T860I | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1183962640, COSV71409614; called by muse, mutect2, varscan2
- CNGA2 | c.27G>T p.K9N | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV61703151; called by muse, mutect2, varscan2
- CNGA2 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.105); catalogued as COSV61703271; called by muse, mutect2, varscan2
- CNGA2 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.784); catalogued as rs756672330, COSV61705552; ClinVar: benign; called by muse, mutect2, varscan2
- CNGA4 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as rs150327554; called by muse, mutect2, varscan2
- CNKSR1 | c.1988A>G p.E663G (on ENST00000374253 / NM_001297647.2; = p.E656G on NM_006314.3) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV58792896; called by muse, mutect2, varscan2
- CNN3 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54734268; called by muse, mutect2, varscan2
- CNNM1 | c.2843C>A p.P948H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV100763790; called by muse, mutect2, varscan2
- CNOT1 | c.2671A>G p.M891V | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as COSV55322139; called by muse, mutect2
- CNOT6L | c.417G>T p.Q139H (on ENST00000504123 / NM_001286790.2; = p.Q134H on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV53701994; called by muse, mutect2, varscan2
- CNOT7 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63518469; called by muse, mutect2, varscan2
- CNTN1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201037986, COSV61642012; called by muse, mutect2, varscan2
- CNTN1 | c.2454A>C p.K818N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV100751778, COSV61641701; called by muse, mutect2, varscan2
- CNTN4 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs548348880, COSV100639315, COSV61868614; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP2 | c.1961A>G p.N654S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1474278215; called by muse, mutect2, varscan2
- CNTNAP5 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.077); catalogued as rs758289984, COSV70471470; called by muse, mutect2, varscan2
- COBL | c.3709G>A p.A1237T | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374766330; called by muse, mutect2, varscan2
- COBL | c.2459C>T p.S820F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as rs1197423010; called by muse, mutect2, varscan2
- COBLL1 | c.2620C>T p.P874S (on ENST00000392717; = p.P836S on NM_014900.5) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV52066501; called by muse, mutect2, varscan2
- COG1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV55431012; called by muse, varscan2
11,944 further variants in this file (8,556 protein-altering or splice-affecting, 3,133 silent, 255 other) are not listed here.
